Gene-level copy-number profile of tumor specimen TARGET-40-PAUBIT-01A from TARGET case TARGET-40-PAUBIT, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.4 years (4,513 days).
Specimen TARGET-40-PAUBIT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.d05149f9-5345-5efc-ae5a-49d3119054d2.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAUBIT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 401 have no estimate.
https://portal.gdc.cancer.gov/files/692ef667-f388-4d25-90da-c5cdc98e6e76

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 963; copy number 1: 3,224; copy number 2: 18,159; copy number 3: 17,295; copy number 4: 9,671; copy number 5: 5,195; copy number 6: 2,199; copy number 7: 2,181; copy number 8: 181; copy number 9: 121; copy number 10: 192; copy number 11: 236; copy number 12: 17; copy number 13: 57; copy number 14: 318; copy number 16: 93; copy number 17: 7; copy number 18: 61; copy number 19: 31; copy number 20: 4; copy number 23: 17.

Homozygous deletions (total copy number 0; autosomes only): 438 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,810,446–248,919,946, 7 genes: SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.
- chr2:38,814–314,373, 7 genes (within-gene range 0–1): FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3.
- chr2:241,881,363–242,078,722, 1 gene (within-gene range 0–1): LINC01237.
- chr2:242,001,209–242,160,153, 8 genes: AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2.
- chr3:11,745–409,417, 7 genes (within-gene range 0–1): LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6.
- chr3:115,802,363–117,139,389, 1 gene (within-gene range 0–2): LSAMP.
- chr3:116,552,473–117,027,039, 10 genes: LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr4:53,286–202,303, 4 genes (within-gene range 0–1): ZNF595, AC253576.1, ZNF718, AC253576.2.
- chr5:58,198–58,915, 1 gene: AC113430.1.
- chr7:159,231,435–159,233,377, 1 gene: PIP5K1P2.
- chr8:150,584–264,703, 11 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2.
- chr8:39,309,909–39,522,852, 3 genes: AC105185.1, ADAM5, ADAM3A.
- chr9:14,475–22,214,672, 323 genes (broad region; genes not listed).
- chr10:46,888–689,668, 12 genes: TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26.
- chr11:134,945,118–135,075,908, 5 genes: AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr12:66,767–178,455, 3 genes (within-gene range 0–3): IQSEC3, AC026369.3, AC026369.1.
- chr13:107,163,510–107,867,496, 1 gene (within-gene range 0–1): FAM155A.
- chr13:107,465,984–109,808,252, 24 genes: AL445649.1, MIR1267, FAM155A-IT1, AL359436.1, AL136964.1, LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, AL138694.1, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1.
- chr18:80,034,346–80,247,514, 9 genes (within-gene range 0–1): AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,157 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:96,583,209–99,244,794, 25 genes, copy number 5 (within-gene range 4–5): RN7SL831P, NDUFS5P2, RPL7P9, RN7SKP270, PTBP2, DPYD, DPYD-AS1, DPYD-IT1, SEC63P1, RPL26P9, AC114878.1, DPYD-AS2, AC114878.2, MIR137HG, BX005019.1, MIR2682, MIR137, AC104453.1, NFU1P2, LINC01776, AC095031.1, SNX7, PLPPR5, AL445433.2, AL445433.1.
- chr1:102,763,322–108,076,020, 39 genes, copy number 5: AC099567.1, COL11A1, SOD2P1, AC095032.2, AC095032.1, RN7SKP285, RNPC3, AMY2B, ACTG1P4, AMY2A, AMY1A, AC105272.1, AMY1B, AMYP1, AMY1C, AL136455.1, AC092506.1, FTLP17, AL591888.1, CDK4P1, LINC01676, SEPTIN2P1, AL512844.2, AL512844.1, LINC01677, AL355306.2, AL355306.1, AL499605.1, AL596327.1, MTATP6P14, MTCO1P14, LINC01661, PRMT6, NTNG1, NDUFA4P1, VAV3, MIR7852, VAV3-AS1, LINC02785.
- chr1:114,089,291–154,469,450, 658 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:81,418,723–148,021,604, 1,248 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:225,698,254–225,762,112, 3 genes, copy number 5: AC016717.1, AC016717.2, AC016717.3.
- chr3:84,881,984–87,993,787, 26 genes, copy number 5–6 (within-gene range 4–6): LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P.
- chr4:48,497,357–48,780,322, 1 gene, copy number 7 (within-gene range 4–7): FRYL.
- chr4:48,805,212–77,819,615, 454 genes, copy number 5–7 (broad region; genes not listed).
- chr5:36,666,214–36,725,195, 1 gene, copy number 5 (within-gene range 3–5): AC008957.1.
- chr5:36,861,736–45,895,970, 146 genes, copy number 5 (broad region; genes not listed).
- chr5:51,963,992–54,415,238, 33 genes, copy number 5 (within-gene range 2–5): AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1, AC008873.1, LINC01033, RPL37P25.
- chr6:36,594,353–68,329,899, 490 genes, copy number 6–23 (within-gene range 4–23) (broad region; genes not listed).
- chr7:2,474,844–8,344,516, 135 genes, copy number 9–10 (broad region; genes not listed).
- chr7:18,086,949–19,002,416, 1 gene, copy number 10 (within-gene range 2–10): HDAC9.
- chr7:18,807,993–26,647,305, 127 genes, copy number 8–11 (broad region; genes not listed).
- chr7:37,419,628–38,025,695, 9 genes, copy number 8–11: AC078843.1, Y_RNA, NECAP1P1, GPR141, EPDR1, GPR141BP, AC018634.1, NME8, SFRP4.
- chr7:48,902,556–48,927,454, 2 genes, copy number 7: GDI2P1, CDC14C.
- chr8:39,106,990–39,284,917, 2 genes, copy number 6 (within-gene range 4–6): ADAM32, RPL3P10.
- chr8:39,522,976–65,184,210, 383 genes, copy number 5–6 (within-gene range 0–6) (broad region; genes not listed).
- chr8:66,432,486–69,104,242, 41 genes, copy number 5 (within-gene range 4–5): AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592.
- chr8:75,302,296–78,805,523, 28 genes, copy number 5: HIGD1AP6, PKMP4, HNF4G, AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1, AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7.
- chr9:34,084,332–41,701,096, 271 genes, copy number 5 (broad region; genes not listed).
- chr10:44,712–46,884, 1 gene, copy number 5: AL713922.1.
- chr10:33,096,257–58,399,220, 390 genes, copy number 5–7 (broad region; genes not listed).
- chr11:44,047,981–71,252,577, 1,023 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr11:70,862,790–80,762,826, 281 genes, copy number 5 (broad region; genes not listed).
- chr12:15,107,783–21,541,249, 80 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:27,332,854–70,243,379, 1,085 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr13:18,467,172–19,783,019, 53 genes, copy number 5 (within-gene range 2–5): ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1, ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P.
- chr14:18,333,726–23,311,751, 381 genes, copy number 6–8 (broad region; genes not listed).
- chr15:19,878,555–37,967,724, 565 genes, copy number 5–7 (broad region; genes not listed).
- chr17:7,717,354–27,003,259, 564 genes, copy number 7–16 (within-gene range 7–18) (broad region; genes not listed).
- chr19:7,382,834–7,470,241, 1 gene, copy number 5 (within-gene range 4–7): AC008878.3.
- chr19:7,395,113–13,880,757, 379 genes, copy number 5 (within-gene range 4–7) (broad region; genes not listed).
- chr19:19,033,575–35,451,767, 455 genes, copy number 5–6 (broad region; genes not listed).
- chr20:21,569,976–30,312,480, 148 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr21:17,901,263–20,803,816, 29 genes, copy number 5 (within-gene range 4–5): CHODL, AF130417.1, TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320.
- chr22:16,405,330–27,225,134, 599 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,211. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
